Somatic mutation profile of tumor specimen TCGA-GN-A266-06A (aliquot TCGA-GN-A266-06A-11D-A197-08) from TCGA case TCGA-GN-A266, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 45.1 years (16,456 days).
Specimen TCGA-GN-A266-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c469377-8e9b-4479-a449-1f5935909015.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GN-A266-10A (Blood Derived Normal), aliquot TCGA-GN-A266-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ee3ebc8-5688-4f32-ab39-78a39835fd1b

The open-access MAF lists 4,657 somatic variants for this specimen: 2,954 protein-altering or splice-affecting, 1,608 silent, 95 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,702, Silent 1,608, Nonsense Mutation 172, Intron 39, Splice Region 38, RNA 27, Splice Site 26, 3'UTR 10, 5'Flank 7, 5'UTR 6, 3'Flank 6, Frame Shift Ins 5.

Variants (750 of 4,657; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CUBN | c.7906C>T p.R2636* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as rs137998687; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAI2 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs137853226, COSV56492973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNH2 | c.1894C>T p.P632S | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs199473527, CM002306, CM133171, COSV51217661; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- KNSTRN | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 24/38 reads (63%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as rs868438023, COSV51103508; ClinVar: likely pathogenic; called by muse, varscan2
- NGLY1 | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | catalogued as rs146140738, COSV54984601; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 26/110 reads (24%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV61823794; called by muse, mutect2, varscan2
- STK19 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 35/128 reads (27%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs267600971, COSV61712753; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SYT13 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 12/88 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen possibly damaging (0.858); catalogued as rs868559206, COSV50072436, COSV50073637; called by muse, mutect2, varscan2
- TP53 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 22/49 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1555526131, COSV52674926, COSV52693942, COSV52759722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP63 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761885185, COSV53196562, COSV53210463; called by mutect2, varscan2
- WRN | c.3961C>T p.R1321* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as rs1303126572, CM104925, COSV53304820, COSV99989573; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1345C>T p.Q449* (on ENST00000373993 / NM_138932.2; = p.Q441* on NM_014576.4) | Nonsense Mutation (SNP) | VAF 16/67 reads (24%) | catalogued as COSV51014701, COSV99257201; called by muse, mutect2, varscan2
- AADACL2 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.651); catalogued as COSV62931243; called by muse, mutect2, varscan2
- AADACL2 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV62931805; called by muse, mutect2, varscan2
- ABCA12 | c.6371C>T p.S2124F (on ENST00000272895 / NM_173076.3; = p.S1806F on NM_015657.3) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as COSV55963018; called by muse, mutect2, varscan2
- ABCA12 | c.4831G>A p.D1611N (on ENST00000272895 / NM_173076.3; = p.D1293N on NM_015657.3) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.405); catalogued as rs775054797, COSV55959959; called by muse, mutect2, varscan2
- ABCA4 | c.3233G>A p.G1078E | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM099662, COSV64676270; called by muse, mutect2, varscan2
- ABCA4 | c.691T>A p.S231T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV64676274; called by muse, mutect2, varscan2
- ABCB1 | c.2828C>T p.S943F | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55959245, COSV99713048; called by muse, mutect2, varscan2
- ABCB1 | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55958562, COSV55958958; called by muse, mutect2, varscan2
- ABCB1 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs761584848, COSV55950092; called by muse, mutect2, varscan2
- ABCB11 | c.3874G>A p.G1292R | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55597225; called by muse, mutect2, varscan2
- ABCB11 | c.2702G>A p.S901N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as CM166695, COSV55597244; called by muse, mutect2, varscan2
- ABCB11 | c.680C>T p.T227I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV55597266; called by muse, varscan2
- ABCB5 | c.1789G>A p.D597N (on ENST00000404938 / NM_001163941.2; = p.D152N on NM_178559.6) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as COSV51716847, COSV99327794; called by muse, mutect2, varscan2
- ABCB9 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.546); catalogued as rs770614269, COSV54893560; called by muse, mutect2, varscan2
- ABCC4 | c.1669C>T p.L557F | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65316600; called by muse, mutect2, varscan2
- ABCC8 | c.2390G>A p.R797Q | Missense Mutation (SNP) | VAF 55/355 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs542420774, COSV56855242; called by muse, mutect2, varscan2
- ABCC8 | c.2253C>T p.P751= | Splice Region (SNP) | VAF 105/327 reads (32%) | catalogued as rs142315209; called by muse, mutect2, varscan2
- ABCC9 | c.3791G>A p.W1264* | Nonsense Mutation (SNP) | VAF 60/94 reads (64%) | catalogued as COSV53981235; called by muse, mutect2, varscan2
- ABCC9 | c.2663G>A p.G888E | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53981254; called by muse, mutect2, varscan2
- ABCD2 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV58053915; called by muse, mutect2, varscan2
- ABCD2 | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58049718; called by muse, mutect2, varscan2
- AC008397.2 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs759923759, COSV53208782; called by mutect2, varscan2
- AC008676.3 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV56637073, COSV56638099; called by muse, mutect2, varscan2
- AC090517.4 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.611); catalogued as rs1162873316, COSV50999248; called by mutect2, varscan2
- AC098582.1 | c.2623A>T p.K875* | Nonsense Mutation (SNP) | VAF 10/16 reads (63%) | catalogued as COSV52023358; called by muse, mutect2, varscan2
- AC100868.1 | c.1307C>T p.S436F | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.02); catalogued as COSV51848021; called by muse, mutect2, varscan2
- ACAD9 | c.1356C>T p.I452= | Splice Region (SNP) | VAF 26/88 reads (30%) | catalogued as COSV58309278; called by muse, mutect2, varscan2
- ACADS | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 108/185 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781528570, COSV54369892; called by muse, mutect2, varscan2
- ACADVL | c.1117dup p.I373Nfs*22 | Frame Shift Ins (INS) | VAF 58/144 reads (40%) | catalogued as rs778988790; called by mutect2, pindel, varscan2
- ACAN | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs374218750, COSV61366471; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACAP2 | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100462545; called by muse, mutect2, varscan2
- ACAP2 | c.615A>T p.Q205H | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100462548; called by muse, mutect2, varscan2
- ACE | c.2176G>A p.D726N | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT tolerated (0.55); PolyPhen benign (0.045); catalogued as COSV52011384; called by muse, mutect2, varscan2
- ACMSD | c.759G>A p.M253I | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV51608690; called by muse, mutect2, varscan2
- ACOT12 | c.509A>T p.D170V | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs779496011, COSV56896977; called by muse, mutect2, varscan2
- ACOXL | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV67737674; called by muse, mutect2, varscan2
- ACP6 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.299); catalogued as rs1553210266, COSV65077649; called by muse, mutect2, varscan2
- ACP7 | c.714C>A p.H238Q | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58700421; called by muse, mutect2, varscan2
- ACRBP | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57524919; called by muse, mutect2, varscan2
- ACSBG2 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.64); catalogued as COSV53126803; called by muse, mutect2, varscan2
- ACSL5 | c.1000C>T p.R334W (on ENST00000354273; = p.R390W on NM_016234.3) | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as rs751370879, COSV61132665; called by muse, mutect2, varscan2
- ACSM2A | c.364G>A p.V122M (on ENST00000219054; = p.V43M on NM_001308169.2) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as COSV54588088; called by muse, mutect2, varscan2
- ACSM2A | c.1291G>A p.D431N (on ENST00000219054; = p.D352N on NM_001308169.2) | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs749299994, COSV54583784; called by muse, mutect2, varscan2
- ACSM5 | c.1718G>A p.R573Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs371032043; called by mutect2, varscan2
- ACTC1 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.953); catalogued as COSV51760608; called by muse, mutect2, varscan2
- ACTC1 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51760624; called by muse, mutect2, varscan2
- ACTL6B | c.1202G>A p.G401D | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV50517259; called by muse, mutect2, varscan2
- ACTR1A | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64023601, COSV64023965; called by muse, mutect2, varscan2
- ACTRT2 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs780802847, COSV65760099; called by muse, mutect2, varscan2
- ADAM18 | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1268455134, COSV55852179; called by muse, mutect2, varscan2
- ADAM19 | c.247A>T p.N83Y | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57436175; called by muse, mutect2, varscan2
- ADAM2 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.458); catalogued as COSV55865564, COSV99697377; called by muse, varscan2
- ADAM22 | c.1912G>A p.G638R | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99067240; called by muse, varscan2
- ADAM23 | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.125); catalogued as rs758501499, COSV100008282; called by muse, varscan2
- ADAM28 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56103607; called by muse, mutect2, varscan2
- ADAM28 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV56103625; called by muse, mutect2, varscan2
- ADAM28 | c.1089G>A p.M363I | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747083377, COSV56101323, COSV99737647; called by muse, varscan2
- ADAM28 | c.1481G>A p.G494D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs892008783, COSV56103002, COSV56103665; called by muse, mutect2, varscan2
- ADAM30 | c.1624C>T p.R542* | Nonsense Mutation (SNP) | VAF 186/576 reads (32%) | catalogued as rs773182987, COSV65561772; called by muse, mutect2, varscan2
- ADAM33 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62936251; called by muse, mutect2, varscan2
- ADAM7 | c.1198C>T p.H400Y | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs867000380, COSV51544305; called by muse, mutect2, varscan2
- ADAMDEC1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs868610362, COSV56474181; called by muse, mutect2, varscan2
- ADAMTS13 | c.2222C>T p.P741L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV63022565; called by muse, mutect2, varscan2
- ADAMTS13 | c.2998C>T p.R1000C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs782761491, COSV63022569; called by muse, mutect2, varscan2
- ADAMTS14 | c.3557G>A p.G1186E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV64599375, COSV64605043; called by muse, mutect2, varscan2
- ADAMTS16 | c.1883C>T p.S628F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57001508; called by muse, mutect2, varscan2
- ADAMTS20 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV67125970; called by muse, mutect2, varscan2
- ADAMTS20 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.25); PolyPhen benign (0.041); catalogued as rs751344474, COSV67136679; called by muse, mutect2, varscan2
- ADAMTS6 | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV66863166; called by muse, varscan2
- ADAMTS8 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.056); catalogued as rs768264811, COSV99961346; called by mutect2, varscan2
- ADAMTSL1 | c.89A>C p.E30A | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52821464; called by muse, mutect2, varscan2
- ADAMTSL2 | c.824A>G p.K275R | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.065); catalogued as COSV63205623; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3040G>A p.E1014K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as COSV54461199; called by muse, mutect2, varscan2
- ADCY10 | c.2999G>A p.G1000E | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.541); catalogued as COSV63243521; called by muse, mutect2, varscan2
- ADCY4 | c.2502G>A p.M834I | Missense Mutation (SNP) | VAF 65/128 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV60256490; called by muse, mutect2, varscan2
- ADCY8 | c.3620G>A p.R1207K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53920628; called by muse, varscan2
- ADCY8 | c.3488G>A p.G1163E | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267601769, COSV53899204; called by muse, varscan2
- ADD2 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.334); catalogued as COSV52467727; called by muse, mutect2, varscan2
- ADGRB2 | c.2792C>T p.S931F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.18); catalogued as rs768974002; called by muse, mutect2, varscan2
- ADGRB3 | c.3527C>T p.S1176L | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as rs142863825, COSV53234039; called by muse, mutect2, varscan2
- ADGRB3 | c.3595G>A p.V1199I | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs1233594189, COSV53237726, COSV53246916; called by muse, mutect2, varscan2
- ADGRE1 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.066); catalogued as COSV51679096, COSV51679698; called by muse, mutect2, varscan2
- ADGRE1 | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51674601; called by muse, mutect2
- ADGRF2 | c.386G>A p.G129E (on ENST00000296862 / NM_001368115.2; = p.G61E on NM_153839.7) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57286647; called by muse, mutect2, varscan2
- ADGRF5 | c.3986A>G p.E1329G | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51938165; called by muse, mutect2, varscan2
- ADGRG4 | c.3011C>T p.S1004F | Missense Mutation (SNP) | VAF 60/88 reads (68%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.723); catalogued as COSV54963417; called by muse, mutect2, varscan2
- ADGRL2 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs757781676, COSV54683574, COSV54689423; called by muse, mutect2, varscan2
- ADGRL2 | c.2636G>A p.R879Q (on ENST00000370717 / NM_001366005.1; = p.R866Q on NM_012302.4) | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373312947; called by muse, mutect2, varscan2
- ADGRL4 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs764619199, COSV66059595; called by muse, mutect2, varscan2
- ADGRV1 | c.8471G>A p.G2824E | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67992132; called by muse, mutect2, varscan2
- ADH1B | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV59297966; called by muse, mutect2, varscan2
- ADH1C | c.838C>A p.L280M | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV72463538, COSV72463593; called by muse, mutect2, varscan2
- ADIPOR2 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63947318; called by muse, mutect2, varscan2
- ADNP | c.493T>A p.Y165N | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62426443; called by muse, mutect2, varscan2
- ADRA1B | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV60703372; called by muse, mutect2, varscan2
- ADRB1 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.989); catalogued as rs748009593, COSV65168213; called by mutect2, varscan2
- AFF2 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 98/151 reads (65%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1172537904, COSV60675852; called by muse, mutect2, varscan2
- AFF2 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 49/70 reads (70%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); catalogued as COSV54001112; called by muse, mutect2, varscan2
- AFF3 | c.3635C>T p.S1212F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV57866297; called by muse, mutect2, varscan2
- AGL | c.3670C>T p.P1224S | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs1417784168, COSV54056433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGMAT | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as rs749470775, COSV65436136; called by muse, mutect2, varscan2
- AGO1 | c.1820C>A p.P607H | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64596105, COSV64596489; called by muse, mutect2, varscan2
- AGXT2 | c.486G>T p.K162N | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs757699506, COSV51489072; called by mutect2, varscan2
- AHNAK2 | c.13624C>T p.L4542F | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV60924804; called by muse, mutect2, varscan2
- AHNAK2 | c.7096C>T p.L2366F | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.963); catalogued as COSV60924814; called by muse, mutect2, varscan2
- AICDA | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs775814283, COSV57564503; called by muse, mutect2, varscan2
- AK7 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50878202; called by muse, mutect2, varscan2
- AK9 | c.3008G>A p.G1003D | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs773958723, COSV58147465; called by muse, mutect2, varscan2
- AK9 | c.34T>C p.F12L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV53422654; called by muse, mutect2, varscan2
- AKAP6 | c.3802C>T p.H1268Y | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV55226417; called by muse, mutect2, varscan2
- AKR1D1 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs867480105, COSV54336599; called by muse, mutect2, varscan2
- AKR1D1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV54339794; called by muse, mutect2, varscan2
- AL035460.1 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as rs755806399, COSV63028429; called by muse, mutect2, varscan2
- AL117348.2 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1336451314, COSV55283768; called by muse, mutect2, varscan2
- AL645922.1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 82/261 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as COSV54961959; called by muse, mutect2, varscan2
- AL645922.1 | c.1992G>T p.A664= | Splice Region (SNP) | VAF 70/270 reads (26%) | catalogued as COSV54961967; called by mutect2, varscan2
- ALDH18A1 | c.1993C>T p.R665* | Nonsense Mutation (SNP) | VAF 38/160 reads (24%) | catalogued as rs751181507, COSV64662072; called by muse, mutect2, varscan2
- ALDH1L1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.005); catalogued as rs752044328, COSV56414396; called by muse, mutect2, varscan2
- ALOX12B | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV59875099; called by muse, mutect2
- ALPK2 | c.2855C>T p.P952L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV64495497; called by muse, mutect2, varscan2
- ALPK3 | c.4388G>A p.R1463K | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.474); catalogued as COSV51937756; called by muse, mutect2
- AMPD1 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.412); catalogued as COSV62417832; called by muse, mutect2
- AMPD3 | c.676G>A p.G226R (on ENST00000396553 / NM_001025389.2; = p.G235R on NM_000480.3) | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV67331946; called by muse, mutect2, varscan2
- AMPH | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1276047312, COSV57751772; called by muse, mutect2, varscan2
- AMY2A | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70214287, COSV70214761; called by muse, mutect2, varscan2
- ANAPC2 | c.1864T>C p.Y622H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60571702; called by muse, mutect2, varscan2
- ANGEL1 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.115); catalogued as rs780024048, COSV51874763; called by muse, mutect2, varscan2
- ANK1 | c.3034G>A p.E1012K | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs907775044, COSV55877464; called by muse, varscan2
- ANK1 | c.716G>A p.G239D | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.875); catalogued as rs867799041, COSV55881818; called by muse, mutect2, varscan2
- ANK2 | c.8831C>T p.T2944I | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as COSV52179213; called by muse, mutect2, varscan2
- ANK3 | c.9002A>C p.K3001T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); catalogued as COSV55073725; called by muse, mutect2, varscan2
- ANK3 | c.8686G>A p.E2896K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as COSV55073735; called by muse, mutect2, varscan2
- ANK3 | c.6311G>A p.G2104E | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.634); catalogued as COSV55073754; called by muse, mutect2, varscan2
- ANKH | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52484559; called by muse, mutect2, varscan2
- ANKRD24 | c.1560A>C p.R520S | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV53673973; called by muse, mutect2
- ANKRD55 | c.1420C>T p.R474* | Nonsense Mutation (SNP) | VAF 17/67 reads (25%) | catalogued as rs1223975152, COSV61949304; called by muse, mutect2, varscan2
- ANKRD7 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.183); catalogued as COSV54555057, COSV54556102; called by muse, mutect2
- ANO2 | c.610C>T p.P204S (on ENST00000356134 / NM_001278597.3; = p.P208S on NM_001278596.3) | Missense Mutation (SNP) | VAF 90/165 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV59006036; called by muse, mutect2, varscan2
- ANO5 | c.1388G>A p.G463E | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.309); catalogued as COSV61088678; called by muse, mutect2, varscan2
- ANXA10 | c.401-1G>A p.X134_splice | Splice Site (SNP) | VAF 17/27 reads (63%) | catalogued as COSV63739859; called by muse, mutect2, varscan2
- AOC3 | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.096); catalogued as rs1381184947, COSV57735231; called by muse, mutect2, varscan2
- AP3B1 | c.1862C>A p.T621N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV54889687; called by muse, mutect2, varscan2
- APOB | c.9703G>A p.A3235T | Missense Mutation (SNP) | VAF 130/338 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV51946548; called by muse, varscan2
- APOB | c.8939C>T p.S2980F | Missense Mutation (SNP) | VAF 100/485 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51941418; called by muse, mutect2, varscan2
- APOB | c.6235G>A p.E2079K | Missense Mutation (SNP) | VAF 116/476 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.037); catalogued as COSV51946085; called by muse, mutect2, varscan2
- APOB | c.2703G>A p.M901I | Missense Mutation (SNP) | VAF 155/416 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV51942541, COSV51945418, COSV51946581; called by muse, mutect2, varscan2
- APOB | c.2470G>A p.D824N | Missense Mutation (SNP) | VAF 107/281 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51946593; called by muse, mutect2, varscan2
- APOBEC3F | c.674T>C p.V225A | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs1267315209; called by muse, mutect2, varscan2
- APOBEC3H | c.441C>A p.N147K | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.241); catalogued as COSV100818853, COSV62379028; called by muse, mutect2, varscan2
- APP | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61002745; called by muse, mutect2, varscan2
- ARAP1 | c.946G>A p.D316N (on ENST00000393609 / NM_001040118.2; = p.D71N on NM_015242.4) | Missense Mutation (SNP) | VAF 127/425 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV61989809; called by muse, mutect2, varscan2
- ARAP2 | c.3667A>G p.K1223E | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as COSV58290297; called by muse, mutect2, varscan2
- ARFGEF3 | c.1874C>T p.S625F | Missense Mutation (SNP) | VAF 55/172 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52466313; called by muse, mutect2, varscan2
- ARHGAP19 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1019639047, COSV57393017; called by muse, mutect2, varscan2
- ARHGAP20 | c.3411G>A p.M1137I | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV52812734; called by muse, mutect2, varscan2
- ARHGAP20 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.125); catalogued as COSV52816623; called by muse, mutect2, varscan2
- ARHGAP20 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52816638; called by muse, mutect2, varscan2
- ARHGAP21 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV64545444; called by muse, mutect2, varscan2
- ARHGAP22 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs953522331, COSV50966089; called by muse, mutect2
- ARHGAP27 | c.1895C>T p.S632L (on ENST00000428638 / NM_001282290.1; = p.S291L on NM_199282.3) | Missense Mutation (SNP) | VAF 53/80 reads (66%) | SIFT tolerated (0.21); PolyPhen benign (0.146); catalogued as rs780110494, COSV65357940; called by muse, mutect2, varscan2
- ARHGAP33 | c.2587C>T p.P863S | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1263178292, COSV50142559; called by muse, mutect2, varscan2
- ARHGAP44 | c.250A>T p.I84F | Missense Mutation (SNP) | VAF 91/163 reads (56%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.449); catalogued as COSV52398485; called by muse, mutect2, varscan2
- ARHGEF10 | c.3812C>T p.S1271L (on ENST00000398564; = p.S1246L on NM_014629.4) | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as rs111978809, COSV50666541; called by muse, mutect2, varscan2
- ARHGEF18 | c.1318C>T p.Q440* (on ENST00000359920 / NM_001130955.2; = p.Q336* on NM_015318.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/76 reads (25%) | catalogued as COSV60472516; called by muse, mutect2, varscan2
- ARHGEF2 | c.2347C>T p.R783W (on ENST00000361247 / NM_001162383.2; = p.R755W on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs762005951, COSV58114982; called by mutect2, varscan2
- ARHGEF3 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1269090226, COSV56330747; called by muse, mutect2, varscan2
- ARHGEF37 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV61369809; called by muse, mutect2, varscan2
- ARID2 | c.4096A>T p.K1366* | Nonsense Mutation (SNP) | VAF 12/17 reads (71%) | catalogued as COSV57611289; called by muse, mutect2, varscan2
- ARID5A | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 11/84 reads (13%) | catalogued as COSV62591583; called by muse, mutect2, varscan2
- ARIH2 | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62705820; called by muse, mutect2, varscan2
- ARMC4 | c.2422G>A p.G808R | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.619); catalogued as rs753521915, COSV59470364; called by muse, mutect2, varscan2
- ARMH4 | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as rs145807752; called by muse, mutect2, varscan2
- ARNT2 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs768601519, COSV57582940; called by muse, mutect2, varscan2
- ARPP21 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as COSV99491357; called by mutect2, varscan2
- ARPP21 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.74); catalogued as COSV51804846; called by muse, mutect2, varscan2
- ARPP21 | c.2129G>A p.G710E | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868857967, COSV51795120; called by muse, mutect2, varscan2
- ARSD | c.1216C>G p.R406G | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as COSV54202087, COSV99471897; called by muse, mutect2, varscan2
- ASAP2 | c.1793G>T p.R598L | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV55634729, COSV55636496; called by muse, mutect2, varscan2
- ASB12 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62857471; called by muse, mutect2, varscan2
- ASB15 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757314130, COSV51924859; called by mutect2, varscan2
- ASB15 | c.1288G>A p.V430I | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV51928334; called by muse, mutect2, varscan2
- ASNS | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750258058, COSV51554883; called by muse, mutect2, varscan2
- ASNS | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV51554910; called by muse, mutect2, varscan2
- ASTL | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV60903705; called by muse, varscan2
- ASTN1 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1192773448, COSV56063225; called by muse, mutect2, varscan2
- ASTN2 | c.1609G>A p.E537K (on ENST00000313400 / NM_001365069.1; = p.E486K on NM_014010.5) | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV57767427; called by muse, mutect2, varscan2
- ASTN2 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.267); catalogued as rs1267305407, COSV57804592; called by muse, varscan2
- ASXL3 | c.6527G>A p.G2176E | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52474737; called by muse, mutect2, varscan2
- ATAD2 | c.1210C>T p.R404* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as rs558571857, COSV54880415, COSV99784425; called by muse, mutect2, varscan2
- ATF7IP2 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV61094801; called by muse, mutect2, varscan2
- ATMIN | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as rs199541307, COSV55145212; called by muse, mutect2, varscan2
- ATP10B | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs746133946, COSV58780257; called by muse, mutect2, varscan2
- ATP12A | c.1560G>A p.M520I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV54520462; called by muse, mutect2, varscan2
- ATP13A4 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55070085; called by muse, mutect2, varscan2
- ATP13A5 | c.3335C>T p.S1112L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs762089471, COSV60873009; called by muse, mutect2, varscan2
- ATP13A5 | c.3113C>T p.S1038L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV60873018; called by muse, mutect2, varscan2
- ATP13A5 | c.2551G>A p.G851R | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60866141; called by muse, mutect2, varscan2
- ATP2A1 | c.2944G>A p.E982K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs538702357, CM1411191, COSV62869021; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2A2 | c.2594C>T p.S865F | Missense Mutation (SNP) | VAF 50/75 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1223207569; called by muse, mutect2, varscan2
- ATP2B2 | c.3140C>T p.P1047L (on ENST00000352432; = p.P1013L on NM_001683.5) | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59504409; called by muse, varscan2
- ATP2B3 | c.2774T>A p.M925K | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54856926; called by muse, mutect2, varscan2
- ATP6V0A1 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.303); catalogued as COSV52876712; called by muse, mutect2, varscan2
- ATP6V1G2 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as rs761196920, COSV58215036; called by muse, mutect2, varscan2
- ATP6V1G3 | c.83G>A p.R28K | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.5); catalogued as rs1342309127, COSV55280253; called by muse, mutect2
- ATP6V1H | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100778883, COSV62218917; called by muse, mutect2, varscan2
- ATP8B3 | c.1019G>A p.R340K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV59546631; called by muse, mutect2, varscan2
- ATP8B4 | c.1991C>T p.S664L | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs1419911517, COSV52717040; called by muse, mutect2, varscan2
- ATP8B4 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs745355532, COSV52708582; called by mutect2, varscan2
- ATRN | c.3434G>A p.R1145Q | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV53532126; called by muse, mutect2, varscan2
- ATRNL1 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV61803792, COSV61803975; called by muse, mutect2, varscan2
- ATRX | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT tolerated (0.65); PolyPhen benign (0.022); catalogued as COSV64869985; called by muse, mutect2, varscan2
- ATXN7L2 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 137/431 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.974); catalogued as COSV63992675; called by muse, mutect2, varscan2
- AUTS2 | c.1573C>T p.H525Y | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61422529; called by muse, mutect2, varscan2
- AVPR1A | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 60/94 reads (64%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as rs1424319046, COSV54547616; called by muse, mutect2, varscan2
- AXDND1 | c.2692G>A p.E898K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV62646270; called by muse, mutect2, varscan2
- AZGP1 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0.011); catalogued as COSV52798890; called by muse, mutect2
- B3GAT1 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1194822057, COSV56999766; called by muse, mutect2
- B3GNT3 | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV57953672; called by muse, mutect2, varscan2
- B4GALT1 | c.695T>C p.F232S | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65708672; called by muse, mutect2, varscan2
- BAG3 | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1234192838, COSV64842458; called by muse, mutect2, varscan2
- BCAM | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 98/338 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as COSV54302264; called by muse, mutect2, varscan2
- BCAT1 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 54/93 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as rs778920280, COSV53915689; called by muse, mutect2, varscan2
- BCHE | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV52260463; called by muse, mutect2, varscan2
- BCL11A | c.1559C>T p.S520F (on ENST00000335712 / NM_001365609.1; = p.S554F on NM_018014.4) | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV59634033; called by muse, mutect2, varscan2
- BCL11B | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV61735288; called by muse, mutect2, varscan2
- BCO2 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63064415; called by muse, mutect2, varscan2
- BDH1 | c.954G>A p.M318I | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.391); catalogued as COSV64019383; called by muse, mutect2, varscan2
- BDNF | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs1349681470, COSV59233092, COSV59234846; called by muse, mutect2, varscan2
- BEND2 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 52/88 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV66216793, COSV66216973; called by muse, mutect2, varscan2
- BICRA | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV67605884; called by muse, mutect2, varscan2
- BIRC5 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV56957082; called by muse, mutect2, varscan2
- BIRC6 | c.9063A>T p.E3021D | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.108); catalogued as COSV70198774, COSV70203835; called by muse, mutect2, varscan2
- BLNK | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV56413721; called by muse, mutect2, varscan2
- BMP4 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753312749, COSV55415763; called by muse, mutect2, varscan2
- BMPR2 | c.2507C>T p.T836I | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV65809888; called by muse, mutect2, varscan2
- BMS1 | c.3308C>T p.P1103L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV65734950; called by muse, mutect2, varscan2
- BPIFA1 | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as COSV62823849; called by muse, mutect2, varscan2
- BPTF | c.4142C>T p.S1381L | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as COSV58843651; called by muse, mutect2, varscan2
- BRD4 | c.3629C>T p.P1210L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs1489035830, COSV54581611; called by muse, mutect2, varscan2
- BRF1 | c.1160G>A p.G387D | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV59272212; called by muse, mutect2, varscan2
- BRINP1 | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.879); catalogued as rs1247843831, COSV56296057; called by muse, varscan2
- BRINP2 | c.1975G>A p.E659K | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.202); catalogued as COSV64179297; called by muse, mutect2, varscan2
- BRINP3 | c.2108T>A p.L703Q | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66526605, COSV66530408; called by muse, mutect2, varscan2
- BRINP3 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66527640; called by muse, varscan2
- BRINP3 | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.001); catalogued as COSV66535317; called by muse, mutect2, varscan2
- BST1 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.113); catalogued as rs113632818, COSV53945345; called by muse, mutect2, varscan2
- BTLA | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV57938828, COSV57939745; called by muse, mutect2, varscan2
- BTN3A1 | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.873); catalogued as COSV50025222; called by muse, mutect2, varscan2
- BTNL3 | c.984G>C p.K328N | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV61565448, COSV61566204; called by muse, mutect2, varscan2
- BTNL8 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1385843482, COSV51457635, COSV51460582; called by muse, varscan2
- C10orf71 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs985271678, COSV100109959, COSV60505874; called by muse, mutect2, varscan2
- C11orf42 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1189483632, COSV56413667; called by muse, mutect2, varscan2
- C11orf53 | c.500T>C p.L167P | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV54722281; called by muse, mutect2, varscan2
- C11orf80 | c.863A>G p.N288S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as COSV60930631; called by muse, mutect2, varscan2
- C12orf42 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV59388238; called by muse, mutect2, varscan2
- C12orf50 | c.1028G>A p.R343K | Missense Mutation (SNP) | VAF 53/92 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV53897681; called by muse, mutect2, varscan2
- C12orf56 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV61487126; called by muse, mutect2, varscan2
- C14orf28 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57333349; called by muse, mutect2, varscan2
- C15orf48 | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs766873845, COSV60223602; called by muse, mutect2, varscan2
- C16orf78 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.59); catalogued as COSV54557773; called by muse, mutect2, varscan2
- C1QC | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV65889955; called by muse, mutect2, varscan2
- C1RL | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV56926217; called by muse, mutect2, varscan2
- C1orf105 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs757473702, COSV62959741; called by muse, mutect2, varscan2
- C1orf127 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV65437313; called by muse, mutect2, varscan2
- C1orf87 | c.272A>G p.N91S | Missense Mutation (SNP) | VAF 95/270 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs765356998, COSV64598130; called by muse, mutect2, varscan2
- C2 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 106/325 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV54960392; called by muse, mutect2, varscan2
- C20orf85 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs375930485, COSV64519777; called by muse, mutect2, varscan2
- C21orf62 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as COSV66672481; called by muse, mutect2, varscan2
- C2CD3 | c.5831T>G p.I1944S | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.584); catalogued as COSV58097804; called by muse, mutect2, varscan2
- C2orf78 | c.1921G>A p.G641R | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs982633903, COSV68518752; called by muse, mutect2, varscan2
- C4BPA | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV65537203; called by muse, mutect2, varscan2
- C5 | c.2504G>A p.R835Q | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868770830, COSV56330830; called by muse, mutect2, varscan2
- C6orf58 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.056); catalogued as COSV61667048; called by muse, mutect2, varscan2
- C7 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1038370285; called by muse, varscan2
- C7 | c.1139G>A p.G380E | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57482775; called by muse, varscan2
- C8A | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV63485845; called by muse, mutect2, varscan2
- C8B | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV64776531; called by muse, mutect2, varscan2
- C8orf34 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); catalogued as rs758310264, COSV100447914; called by muse, mutect2, varscan2
- C9 | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as rs1361939161, COSV54679805; called by muse, mutect2, varscan2
- C9orf152 | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); catalogued as rs781225120, COSV68763055; called by muse, mutect2, varscan2
- CA1 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 26/72 reads (36%) | catalogued as COSV56277385, COSV56279613; called by muse, mutect2, varscan2
- CA9 | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61407276; called by muse, mutect2, varscan2
- CAB39L | c.132A>T p.K44N | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV61716228; called by muse, mutect2, varscan2
- CABYR | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV59112155; called by muse, varscan2
- CACHD1 | c.1565T>A p.L522H | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51557962; called by muse, mutect2, varscan2
- CACHD1 | c.2237C>T p.S746F | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs145700540, COSV51560714; called by muse, mutect2, varscan2
- CACNA1B | c.5693A>G p.E1898G | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV53141129; called by muse, mutect2
- CACNA1E | c.5619G>A p.M1873I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV62410304; called by mutect2, varscan2
- CACNA1G | c.5818C>T p.Q1940* | Nonsense Mutation (SNP) | VAF 13/21 reads (62%) | catalogued as COSV61734529; called by muse, mutect2, varscan2
- CACNA1H | c.6532G>A p.A2178T | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs771909122, COSV52357051; called by muse, mutect2, varscan2
- CACNA2D2 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.996); catalogued as COSV56564037; called by muse, mutect2, varscan2
- CACNG1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 55/80 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.385); catalogued as rs760216442, COSV56826298, COSV56827091; called by muse, mutect2, varscan2
- CADM3 | c.977C>T p.S326F (on ENST00000368125 / NM_001127173.3; = p.S360F on NM_021189.5) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV63676982; called by muse, mutect2, varscan2
- CADPS | c.3555C>T p.F1185= | Splice Region (SNP) | VAF 47/153 reads (31%) | catalogued as rs770554516, COSV51894992; called by muse, mutect2, varscan2
- CADPS | c.3254A>G p.E1085G | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51895011; called by muse, mutect2, varscan2
- CADPS | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs747130261, COSV51895029; called by muse, mutect2, varscan2
- CADPS2 | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57364040; called by muse, mutect2, varscan2
- CALCR | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1049841885, COSV64010822; called by muse, mutect2, varscan2
- CALML5 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV66702671; called by muse, mutect2, varscan2
- CAMK1D | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs143417427; called by muse, mutect2, varscan2
- CAMK4 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.071); catalogued as COSV56679035; called by muse, varscan2
- CAMTA1 | c.2062G>A p.G688R | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.235); catalogued as rs749771715, COSV57918920; called by muse, mutect2, varscan2
- CANT1 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 142/211 reads (67%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV56606310; called by muse, mutect2, varscan2
- CAP2 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV57735346; called by muse, mutect2, varscan2
- CAPN13 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as rs373913163, COSV54429576; called by muse, mutect2, varscan2
- CARD11 | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1251262286, COSV62756526; called by muse, mutect2, varscan2
- CASP14 | c.471A>C p.Q157H | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.449); catalogued as COSV55666200; called by muse, mutect2, varscan2
- CASQ2 | c.53G>A p.R18K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV54772883; called by muse, mutect2, varscan2
- CASR | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0.026); catalogued as COSV56136798; called by muse, mutect2
- CASR | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.079); catalogued as rs1287075426, COSV56139780; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASS4 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV64387308; called by muse, mutect2, varscan2
- CASZ1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.63); catalogued as rs756472680, COSV59739519; called by muse, mutect2, varscan2
- CATSPER1 | c.1689C>T p.L563= | Splice Region (SNP) | VAF 13/47 reads (28%) | catalogued as COSV56411915, COSV56412673; called by muse, mutect2, varscan2
- CATSPER4 | c.685T>C p.S229P | Missense Mutation (SNP) | VAF 148/455 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs755067675, COSV58794116; called by muse, mutect2, varscan2
- CATSPERD | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs369818912; called by muse, varscan2
- CAVIN2 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58423237; called by muse, mutect2, varscan2
- CBFA2T3 | c.1042G>T p.A348S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.132); catalogued as COSV51931112; called by muse, mutect2, varscan2
- CCAR1 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56267135; called by muse, mutect2, varscan2
- CCBE1 | c.785G>A p.G262E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV67951046; called by muse, mutect2, varscan2
- CCDC102B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as COSV60149967; called by muse, varscan2
- CCDC141 | c.4162C>T p.P1388S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.02); catalogued as COSV55379108; called by muse, mutect2, varscan2
- CCDC141 | c.3566G>A p.G1189D | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55379142; called by muse, varscan2
- CCDC170 | c.444-1G>A p.X148_splice | Splice Site (SNP) | VAF 3/18 reads (17%) | catalogued as COSV53344345, COSV53347724; called by muse, mutect2
- CCDC173 | c.1077G>A p.W359* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV71653845; called by muse, mutect2, varscan2
- CCDC178 | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV100284323; called by muse, mutect2, varscan2
- CCDC186 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.044); catalogued as rs1226695954, COSV65159734; called by muse, mutect2, varscan2
- CCDC198 | c.713G>A p.W238* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV53603023; called by muse, mutect2
- CCDC27 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as rs748892044, COSV53902290; called by muse, mutect2, varscan2
- CCDC39 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs755372916, COSV56479163; called by muse, mutect2, varscan2
- CCDC54 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.778); catalogued as COSV53757969, COSV53759553; called by muse, mutect2, varscan2
- CCDC60 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59548198; called by muse, varscan2
- CCDC60 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772386912, COSV59540809; called by muse, varscan2
- CCDC74B | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.548); catalogued as rs765402726, COSV60103292; called by mutect2, varscan2
- CCDC85A | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); catalogued as rs764849312, COSV68154259; called by muse, mutect2, varscan2
- CCDC88C | c.4472C>T p.S1491F | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.668); catalogued as rs1413663930, COSV57797674; called by muse, mutect2, varscan2
- CCL21 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as COSV52399050; called by muse, mutect2, varscan2
- CCN2 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866211072, COSV63466725; called by muse, mutect2, varscan2
- CCNA1 | c.1368G>A p.M456I | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.98); PolyPhen benign (0.005); catalogued as COSV55223241; called by muse, varscan2
- CCR5 | c.307C>T p.L103F | Missense Mutation (SNP) | VAF 68/249 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV52752238; called by muse, mutect2, varscan2
- CCT5 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV54725019; called by muse, mutect2, varscan2
- CCT8L2 | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63463387, COSV63463859; called by muse, varscan2
- CD163 | c.3421G>A p.E1141K | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63135928; called by muse, mutect2, varscan2
- CD163L1 | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 45/67 reads (67%) | SIFT tolerated (0.73); PolyPhen benign (0.174); catalogued as rs760155715, COSV58021752; called by muse, mutect2, varscan2
- CD163L1 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV58010812; called by muse, mutect2, varscan2
- CD1B | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV63803723; called by muse, mutect2, varscan2
- CD1C | c.904A>G p.M302V | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs770103816, COSV63807177; called by muse, mutect2, varscan2
- CD1E | c.1051G>A p.G351R | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV63772301; called by muse, varscan2
- CD2 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101040478, COSV65644647; called by muse, mutect2, varscan2
- CD2 | c.901G>A p.G301R | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV65644652; called by muse, varscan2
- CD2 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs746292283, COSV65644327; called by muse, varscan2
- CD207 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.082); catalogued as COSV69652454; called by muse, mutect2, varscan2
- CD34 | c.97C>T p.L33F | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.033); catalogued as COSV60414498; called by muse, mutect2, varscan2
- CD93 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55667693; called by muse, mutect2, varscan2
- CDC20B | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57055434; called by muse, mutect2, varscan2
- CDC25A | c.1126C>T p.L376F | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as COSV56771837; called by muse, mutect2, varscan2
- CDC40 | c.745T>C p.Y249H | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57011344; called by muse, mutect2, varscan2
- CDC42BPG | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 88/355 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs1488303663, COSV61348607; called by muse, mutect2, varscan2
- CDH10 | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV52591775; called by muse, mutect2, varscan2
- CDH10 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV52591788; called by mutect2, varscan2
- CDH11 | c.2383G>A p.D795N | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.019); catalogued as rs1471732983, COSV51758237, COSV51771976; called by muse, varscan2
- CDH13 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.038); catalogued as rs575477444; called by muse, mutect2, varscan2
- CDH13 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51853612; called by muse, mutect2, varscan2
- CDH16 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55338697; called by muse, mutect2, varscan2
- CDH18 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as COSV56947941; called by muse, mutect2, varscan2
- CDH18 | c.1018A>C p.K340Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.188); catalogued as COSV56947989; called by muse, mutect2, varscan2
- CDH24 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV52980024; called by muse, mutect2, varscan2
- CDH4 | c.1702G>A p.V568M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as rs1360090431, COSV64668667; called by muse, mutect2, varscan2
- CDH5 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1162755551, COSV58519184; called by muse, mutect2, varscan2
- CDH7 | c.917G>A p.G306D | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV59891401; called by muse, varscan2
- CDK13 | c.1957C>T p.P653S | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV51704389; called by muse, mutect2, varscan2
- CDK18 | c.1426G>A p.E476K (on ENST00000506784 / NM_212503.3; = p.E446K on NM_002596.4) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as rs1462641515, COSV63728557; called by muse, mutect2, varscan2
- CDK20 | c.722C>T p.S241F (on ENST00000325303 / NM_001039803.3; = p.S220F on NM_012119.4) | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV57483803; called by muse, varscan2
- CDK5RAP1 | c.1099G>A p.E367K (on ENST00000357886 / NM_001365728.1; = p.E353K on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV59428280; called by mutect2, varscan2
- CDR1 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 40/52 reads (77%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV65164587; called by muse, mutect2, varscan2
- CDRT1 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV55412976; called by mutect2, varscan2
- CDX1 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.015); catalogued as rs777049283, COSV51568386; called by muse, mutect2, varscan2
- CEACAM18 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 35/100 reads (35%) | catalogued as COSV67283718; called by muse, mutect2, varscan2
- CEACAM20 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 131/418 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.09); catalogued as COSV57602705; called by muse, mutect2, varscan2
- CEACAM6 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.093); catalogued as COSV52266541; called by muse, mutect2, varscan2
- CEL | c.1472G>A p.W491* (on ENST00000673714; = p.W488* on NM_001807.6) | Nonsense Mutation (SNP) | VAF 153/393 reads (39%) | catalogued as COSV60828928; called by muse, mutect2, varscan2
- CELA1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs376966959; called by muse, mutect2, varscan2
- CELSR3 | c.6920G>A p.R2307K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV51034865; called by muse, mutect2, varscan2
- CEMIP2 | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.074); catalogued as COSV65488686; called by muse, mutect2, varscan2
- CENPT | c.1249C>T p.L417F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV104375026, COSV54651400; called by muse, mutect2, varscan2
- CEP126 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.46); catalogued as rs145886481, COSV54827270; called by muse, mutect2, varscan2
- CEP250 | c.2708C>T p.A903V | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV61172789; called by muse, mutect2, varscan2
- CEP350 | c.8870C>T p.A2957V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.253); catalogued as COSV100854938, COSV62607766; called by muse, mutect2, varscan2
- CEP76 | c.1837C>T p.L613F | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV50868786, COSV50871054; called by muse, mutect2, varscan2
- CERKL | c.1223G>A p.G408E (on ENST00000339098 / NM_001030311.2; = p.G382E on NM_201548.5) | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs776211842, COSV59211628; called by muse, mutect2, varscan2
- CERS3 | c.174-1G>A p.X58_splice | Splice Site (SNP) | VAF 10/33 reads (30%) | catalogued as COSV52572668; called by muse, mutect2, varscan2
- CES5A | c.1427G>A p.G476E (on ENST00000290567 / NM_001143685.2; = p.G426E on NM_145024.3) | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV51869152; called by muse, mutect2, varscan2
- CETP | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV52363754; called by muse, mutect2, varscan2
- CFAP206 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.047); catalogued as rs757647018, COSV51536055; called by muse, mutect2, varscan2
- CFAP221 | c.1327C>T p.H443Y | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.321); catalogued as COSV54660738; called by muse, mutect2
- CFAP43 | c.3238G>A p.D1080N | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.356); catalogued as COSV53380170; called by muse, mutect2, varscan2
- CFAP46 | c.6892G>A p.D2298N | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as rs199874282, COSV54156794; called by muse, mutect2, varscan2
- CFAP47 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1364476260, COSV52885634; called by muse, mutect2, varscan2
- CFAP47 | c.4451G>A p.G1484E | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.97); PolyPhen benign (0.018); catalogued as COSV57975766; called by muse, mutect2, varscan2
- CFAP54 | c.5701C>T p.L1901F | Missense Mutation (SNP) | VAF 66/107 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV61572136; called by muse, mutect2, varscan2
- CFAP54 | c.7246C>T p.L2416F | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV61574114; called by muse, mutect2, varscan2
- CFAP58 | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV63832687, COSV63835469; called by muse, mutect2, varscan2
- CFAP61 | c.1057G>A p.G353R | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV55641310; called by muse, mutect2, varscan2
- CFAP65 | c.5350G>A p.E1784K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs1157740349, COSV58566381; called by muse, mutect2, varscan2
- CFAP65 | c.5281G>A p.E1761K | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as rs1056787212, COSV58563146; called by muse, mutect2, varscan2
- CFAP69 | c.2603G>A p.R868Q | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1378719540, COSV60185437; called by muse, mutect2, varscan2
- CFAP91 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV56343357; called by muse, mutect2, varscan2
- CFAP94 | c.752G>A p.R251Q (on ENST00000320267 / NM_001352064.2; = p.R257Q on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 270/282 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV57235300; called by muse, mutect2, varscan2
- CFAP94 | c.37G>A p.E13K (on ENST00000320267 / NM_001352064.2; = p.E19K on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 951/1070 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV57235314; called by muse, mutect2, varscan2
- CFH | c.1798G>A p.G600R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (1); PolyPhen probably damaging (0.944); catalogued as COSV66405861; called by muse, mutect2, varscan2
- CFH | c.3481C>T p.P1161S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as CM161601, COSV66411582; called by muse, mutect2, varscan2
- CFH | c.3616C>T p.R1206C | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.502); catalogued as CM100539, COSV66410739; called by muse, mutect2, varscan2
- CFHR2 | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV66381857; called by muse, mutect2, varscan2
- CFHR3 | c.656G>A p.G219D | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV66402951; called by muse, mutect2, varscan2
- CFHR3 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 19/83 reads (23%) | catalogued as COSV66401439; called by muse, mutect2, varscan2
- CFHR5 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV56826134; called by muse, mutect2, varscan2
- CFHR5 | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.025); catalogued as rs776538115, COSV56826155; called by mutect2, varscan2
- CGAS | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.551); catalogued as COSV64808776; called by muse, mutect2, varscan2
- CGB7 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV62282296; called by muse, mutect2, varscan2
- CHAMP1 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV63522918; called by muse, mutect2, varscan2
- CHD5 | c.4607G>A p.G1536E | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1413573305, COSV52421833; called by muse, mutect2
- CHD5 | c.3160G>A p.D1054N | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV52421850; called by muse, varscan2
- CHD5 | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52421865; called by muse, varscan2
- CHDH | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.744); catalogued as COSV55459136; called by muse, mutect2, varscan2
- CHGB | c.1160G>A p.R387K | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV66761413; called by muse, mutect2, varscan2
- CHI3L2 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV63874629; called by muse, mutect2, varscan2
- CHP2 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as rs763717214, COSV55650550; called by muse, varscan2
- CHRD | c.2556G>A p.V852= | Splice Region (SNP) | VAF 39/149 reads (26%) | catalogued as COSV52605693; called by muse, mutect2, varscan2
- CHRDL1 | c.1180G>A p.E394K (on ENST00000372045; = p.E400K on NM_145234.4) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV54327557; called by muse, mutect2, varscan2
- CHRM2 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV57780378; called by muse, mutect2, varscan2
- CHRM3 | c.1439G>A p.R480K | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV55087647; called by muse, mutect2, varscan2
- CHRNA1 | c.340C>T p.P114S (on ENST00000261007 / NM_001039523.3; = p.P89S on NM_000079.4) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV53684424, COSV53685059; called by muse, mutect2, varscan2
- CHRNA3 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58776555; called by muse, mutect2, varscan2
- CHRNB3 | c.1238G>A p.S413N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV51496830; called by muse, mutect2, varscan2
- CHST4 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58297978; called by muse, mutect2, varscan2
- CHST9 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV52445559; called by muse, mutect2, varscan2
- CIBAR2 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV73320674; called by muse, mutect2, varscan2
- CILP | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV56026794; called by muse, mutect2
- CILP2 | c.1891G>A p.D631N | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1221475168, COSV52278613; called by muse, mutect2, varscan2
- CILP2 | c.3166G>A p.G1056S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767078661, COSV52278642; called by mutect2, varscan2
- CLCA2 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV65286913; called by muse, mutect2, varscan2
- CLCN1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV58373065; called by muse, mutect2, varscan2
- CLCN2 | c.835T>C p.F279L | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55603340; called by muse, mutect2, varscan2
- CLCN6 | c.1553C>T p.S518L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs149710478; called by muse, mutect2, varscan2
- CLCNKA | c.499-1G>A p.X167_splice | Splice Site (SNP) | VAF 10/67 reads (15%) | catalogued as COSV100510274; called by muse, varscan2
- CLCNKA | c.1053G>A p.R351= | Splice Region (SNP) | VAF 35/87 reads (40%) | catalogued as COSV58893324, COSV58893601; called by muse, mutect2, varscan2
- CLDN14 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.738); catalogued as rs146755542; called by muse, mutect2, varscan2
- CLDN18 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as COSV100648286, COSV59304274; called by muse, mutect2
- CLDN18 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs763361247, COSV51737549; called by muse, mutect2, varscan2
- CLDN2 | c.468G>A p.M156I | Missense Mutation (SNP) | VAF 55/81 reads (68%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); catalogued as COSV61020890, COSV61021417; called by muse, mutect2, varscan2
- CLEC14A | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as COSV60563303; called by muse, mutect2, varscan2
- CLEC16A | c.2933G>A p.S978N | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs376884507; called by mutect2, varscan2
- CLEC1A | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs771656826, COSV59533457; called by muse, mutect2, varscan2
- CLIC6 | c.1777G>A p.E593K (on ENST00000360731 / NM_001317009.2; = p.E575K on NM_053277.3) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62448807; called by muse, mutect2, varscan2
- CLIP2 | c.804-1G>A p.X268_splice | Splice Site (SNP) | VAF 31/116 reads (27%) | catalogued as COSV56283793; called by muse, varscan2
- CLIP4 | c.1781G>A p.R594K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.084); catalogued as COSV60751330; called by muse, mutect2, varscan2
- CLK2 | c.1310C>T p.P437L (on ENST00000368361 / NM_001294339.2; = p.P436L on NM_003993.4) | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs748129698, COSV56946692; called by muse, mutect2, varscan2
- CLTCL1 | c.2954C>T p.P985L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54236466; called by muse, mutect2, varscan2
- CMA1 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.014); catalogued as rs1053081210; called by muse, mutect2, varscan2
- CMTM7 | c.261G>A p.M87I | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV58551661; called by muse, mutect2, varscan2
- CMYA5 | c.2360G>A p.G787E | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.219); catalogued as COSV71408424; called by muse, mutect2, varscan2
- CNBD1 | c.1162C>T p.Q388* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as COSV73075196; called by muse, mutect2, varscan2
- CNGA3 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as rs370581927; called by muse, varscan2
- CNGA3 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.052); catalogued as COSV55625931, COSV55626763; called by muse, varscan2
- CNGB1 | c.3703G>A p.E1235K | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51904836; called by muse, mutect2, varscan2
- CNGB1 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.863); catalogued as COSV51904848; called by muse, mutect2, varscan2
- CNN1 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV52948083; called by muse, mutect2, varscan2
- CNOT10 | c.1025C>T p.S342L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.335); catalogued as rs866623553, COSV59394123; called by muse, mutect2
- CNTN2 | c.1614G>A p.M538I | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV59351995; called by muse, mutect2, varscan2
- CNTN2 | c.3005G>A p.R1002K | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV59352001; called by muse, mutect2, varscan2
- CNTN3 | c.1850C>A p.S617Y | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55180408, COSV55184908; called by muse, mutect2, varscan2
- CNTN5 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV54279105; called by muse, mutect2
- CNTN5 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54285866; called by muse, mutect2, varscan2
- CNTN5 | c.3052C>T p.H1018Y | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.303); catalogued as rs771967984, COSV54341461; called by mutect2, varscan2
- CNTN6 | c.2000C>T p.P667L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV100611333, COSV63183600; called by muse, mutect2, varscan2
- CNTNAP2 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.439); catalogued as COSV62233386; called by muse, varscan2
- CNTNAP2 | c.3388C>T p.H1130Y | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs867798232; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP2 | c.3713C>T p.S1238L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV62233393; called by muse, mutect2, varscan2
- CNTNAP3 | c.2477C>T p.S826F | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.125); catalogued as COSV52664256; called by muse, mutect2, varscan2
- CNTNAP4 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56694100; called by muse, mutect2, varscan2
- CNTNAP4 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as rs756575759, COSV56694118; called by mutect2, varscan2
- CNTRL | c.6725G>T p.R2242L | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV53049114, COSV53051388; called by muse, mutect2
- COBL | c.3403G>A p.E1135K | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as COSV54354024; called by muse, varscan2
- COL11A1 | c.2567G>A p.G856E | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62197284; called by muse, mutect2, varscan2
- COL12A1 | c.7244T>C p.L2415S | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV59403756; called by muse, mutect2, varscan2
- COL12A1 | c.4408G>A p.E1470K | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as COSV59403765; called by muse, mutect2, varscan2
- COL12A1 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59403777; called by muse, mutect2, varscan2
- COL14A1 | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1364682538; called by muse, mutect2, varscan2
- COL14A1 | c.5258C>T p.S1753F | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV52863671; called by muse, mutect2, varscan2
- COL17A1 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV62228632; called by muse, mutect2, varscan2
- COL19A1 | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as COSV59568102; called by muse, mutect2, varscan2
- COL1A2 | c.2290C>T p.P764S | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); catalogued as COSV51963411; called by muse, mutect2, varscan2
- COL1A2 | c.2381G>A p.R794Q | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1024288536, COSV51955672; called by muse, mutect2, varscan2
- COL1A2 | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as COSV51963431; called by muse, varscan2
- COL1A2 | c.2588C>T p.P863L | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.122); catalogued as COSV51963443; called by muse, mutect2, varscan2
- COL20A1 | c.2353A>T p.K785* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV58924277; called by mutect2, varscan2
- COL21A1 | c.2131C>T p.Q711* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV55174121; called by mutect2, varscan2
- COL21A1 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55163626; called by mutect2, varscan2
- COL21A1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs562696627, COSV55174191; called by muse, mutect2, varscan2
- COL21A1 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55174221; called by muse, mutect2, varscan2
- COL24A1 | c.4613G>A p.R1538Q | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as rs371171500; called by muse, mutect2, varscan2
- COL28A1 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV68083787; called by muse, mutect2, varscan2
- COL3A1 | c.1952G>A p.G651E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58594160; called by muse, mutect2, varscan2
- COL4A3 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.1); catalogued as COSV67418397; called by muse, mutect2, varscan2
- COL4A3 | c.3239G>A p.G1080E | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755128292, CM148115, COSV59258792; called by muse, mutect2, varscan2
- COL4A3 | c.4244G>A p.G1415E | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67418409; called by muse, mutect2, varscan2
- COL4A4 | c.4825G>A p.D1609N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.156); catalogued as COSV61634871; called by muse, mutect2, varscan2
- COL4A4 | c.3508C>A p.P1170T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.259); catalogued as COSV61634874; called by muse, mutect2, varscan2
- COL4A4 | c.3368C>T p.P1123L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs753264064, COSV61634876; called by muse, mutect2, varscan2
- COL4A4 | c.1371G>A p.V457= | Splice Region (SNP) | VAF 16/36 reads (44%) | catalogued as COSV61634878; called by muse, mutect2, varscan2
- COL4A5 | c.1625G>A p.G542E | Missense Mutation (SNP) | VAF 51/81 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60366928, COSV60375553; called by muse, mutect2, varscan2
- COL4A6 | c.1547G>A p.G516E | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57873798; called by muse, mutect2, varscan2
- COL4A6 | c.917G>A p.G306D | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV57873812; called by muse, varscan2
- COL4A6 | c.908G>A p.G303D | Missense Mutation (SNP) | VAF 42/62 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57873818; called by muse, varscan2
- COL5A1 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 22/123 reads (18%) | catalogued as CM050205, COSV65673073; called by muse, mutect2, varscan2
- COL5A1 | c.2767C>T p.P923S | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as COSV100880050, COSV65667439; called by muse, mutect2, varscan2
- COL5A1 | c.3244C>T p.P1082S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.915); catalogued as COSV65673079; called by muse, varscan2
- COL5A2 | c.3721G>A p.D1241N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.225); catalogued as COSV66408648; called by muse, mutect2, varscan2
- COL5A2 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100880389, COSV66412979; called by muse, mutect2, varscan2
- COL6A3 | c.9256C>T p.P3086S | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV55102210; called by muse, mutect2, varscan2
- COL6A5 | c.6069G>A p.M2023I (on ENST00000312481; = p.M2019I on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV55211720; called by muse, mutect2, varscan2
- COL7A1 | c.2611G>A p.G871R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1295859532, COSV60400576; called by muse, mutect2, varscan2
- COL7A1 | c.1344G>A p.W448* | Nonsense Mutation (SNP) | VAF 31/111 reads (28%) | catalogued as COSV60400586; called by muse, mutect2, varscan2
- COL9A1 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.954); catalogued as rs866835663, COSV61836155; called by muse, mutect2, varscan2
- COLGALT2 | c.1514A>C p.E505A | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.215); catalogued as COSV62300232; called by muse, mutect2, varscan2
- COMMD2 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV71946607; called by muse, mutect2, varscan2
- COMTD1 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.244); catalogued as rs1050224198, COSV53687095; called by mutect2, varscan2
- COPA | c.2684C>T p.S895F | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as rs1396829399, COSV54097252; called by muse, mutect2
- CORIN | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56694413; called by muse, mutect2, varscan2
- CORO1A | c.1068G>A p.S356= | Splice Region (SNP) | VAF 20/103 reads (19%) | catalogued as rs752449610, COSV54631875; called by muse, mutect2, varscan2
- CORO2A | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs373733956; called by muse, mutect2, varscan2
- CORO2A | c.269G>A p.W90* | Nonsense Mutation (SNP) | VAF 19/90 reads (21%) | catalogued as COSV59664240; called by muse, varscan2
- CPA3 | c.580A>G p.T194A | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV56046675; called by muse, mutect2, varscan2
- CPA6 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs765895994, COSV52726004; called by mutect2, varscan2
- CPAMD8 | c.1702C>T p.R568C (on ENST00000651564; = p.R521C on NM_015692.5) | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs762584662, COSV52230795; called by muse, mutect2, varscan2
- CPB1 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as rs773945220, COSV51575798; called by muse, mutect2, varscan2
- CPEB3 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.913); catalogued as COSV56461081; called by muse, mutect2, varscan2
- CPN1 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs764344215, COSV64942649; called by muse, mutect2
- CPN1 | c.942T>A p.F314L | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as COSV64942652; called by muse, mutect2
- CPNE4 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV70198170; called by muse, mutect2, varscan2
- CPNE5 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as rs1466412521, COSV55198760; called by muse, mutect2, varscan2
- CPNE8 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1353461310, COSV58848863; called by muse, mutect2, varscan2
- CPT1C | c.1516G>A p.D506N | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs761476419, COSV54921342; called by muse, mutect2, varscan2
- CR1 | c.4734G>A p.W1578* | Nonsense Mutation (SNP) | VAF 22/48 reads (46%) | catalogued as rs1216947356, COSV65461526; called by muse, mutect2, varscan2
- CR2 | c.2042T>C p.V681A | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as COSV65509004; called by muse, mutect2, varscan2
- CR2 | c.2699G>A p.W900* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as COSV65509011; called by muse, mutect2, varscan2
- CREB3L3 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV50246521; called by muse, mutect2, varscan2
- CREB3L4 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV55131163; called by muse, mutect2, varscan2
- CREG2 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61317591; called by muse, varscan2
- CRISP1 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752708678, COSV59994791; called by muse, mutect2
- CROCC | c.2948C>T p.S983F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs1231600904, COSV65011410; called by muse, varscan2
- CRTAM | c.223C>T p.H75Y | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV57070452; called by muse, mutect2, varscan2
- CRYBG2 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.292); catalogued as COSV57488429; called by muse, mutect2, varscan2
- CRYBG3 | c.6376C>A p.L2126I | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99476762; called by muse, mutect2, varscan2
- CRYGN | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV61564230; called by muse, mutect2, varscan2
- CSF1R | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV53840137; called by muse, mutect2, varscan2
- CSMD1 | c.9332G>A p.G3111E (on ENST00000520002; = p.G3110E on NM_033225.6) | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59338867; called by muse, mutect2, varscan2
- CSMD1 | c.5636C>T p.P1879L (on ENST00000520002; = p.P1878L on NM_033225.6) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs541928934, COSV59340940; called by muse, mutect2, varscan2
- CSMD1 | c.4180G>A p.D1394N (on ENST00000520002; = p.D1393N on NM_033225.6) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779702652, COSV59321276, COSV99045826; called by muse, mutect2
- CSMD1 | c.4008G>A p.W1336* (on ENST00000520002; = p.W1335* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV59360112, COSV59361642; called by muse, mutect2, varscan2
- CSMD2 | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV53933978; called by muse, mutect2, varscan2
- CSMD3 | c.6085T>A p.F2029I (on ENST00000297405 / NM_001363185.1; = p.F1925I on NM_052900.3) | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52270420; called by muse, mutect2, varscan2
- CSMD3 | c.5068C>T p.H1690Y (on ENST00000297405 / NM_001363185.1; = p.H1586Y on NM_052900.3) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.792); catalogued as rs267601732, COSV52138124; called by muse, mutect2, varscan2
- CSMD3 | c.2975C>T p.S992F (on ENST00000297405 / NM_001363185.1; = p.S888F on NM_052900.3) | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52270503; called by muse, mutect2, varscan2
- CSMD3 | c.1840C>T p.P614S (on ENST00000297405 / NM_001363185.1; = p.P510S on NM_052900.3) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0.122); catalogued as COSV52270520; called by muse, mutect2, varscan2
- CSMD3 | c.1635G>A p.V545= (on ENST00000297405 / NM_001363185.1; = p.V441= on NM_052900.3) | Splice Region (SNP) | VAF 15/43 reads (35%) | catalogued as rs1195772538, COSV52270544; called by muse, mutect2, varscan2
- CSNK2A1 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1258475591, COSV53933556; called by muse, mutect2, varscan2
- CSPG4 | c.4262C>T p.S1421F | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV57899593; called by muse, mutect2, varscan2
- CST11 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs367809425, COSV100776865; called by muse, mutect2, varscan2
- CSTF3 | c.105G>A p.W35* | Nonsense Mutation (SNP) | VAF 13/93 reads (14%) | catalogued as COSV60613406; called by muse, mutect2, varscan2
- CTAGE1 | c.546G>A p.W182* | Nonsense Mutation (SNP) | VAF 35/94 reads (37%) | catalogued as COSV66943903; called by muse, mutect2, varscan2
- CTAGE6 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV101417868; called by muse, mutect2, varscan2
- CTCFL | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); catalogued as COSV54777566; called by muse, mutect2, varscan2
- CTNNA2 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63589631; called by muse, mutect2, varscan2
- CTNNA2 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV100559522, COSV58169832; called by muse, mutect2, varscan2
- CTNNA2 | c.2718G>A p.W906* (on ENST00000402739 / NM_001282597.3; = p.W858* on NM_004389.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 60/151 reads (40%) | catalogued as COSV58169851; called by muse, mutect2, varscan2
- CTSA | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.143); catalogued as COSV51944054; called by muse, mutect2, varscan2
- CTSV | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.101); catalogued as COSV52345464; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54743217; called by muse, mutect2, varscan2
- CUBN | c.4147C>T p.Q1383* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV64723376; called by muse, mutect2, varscan2
- CUL4A | c.1519C>T p.H507Y (on ENST00000375440 / NM_001008895.4; = p.H407Y on NM_003589.3) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV58374907; called by muse, mutect2, varscan2
- CUL4B | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.204); catalogued as COSV60689644; called by muse, mutect2, varscan2
- CUL5 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as rs764904082, COSV67609809; called by muse, mutect2, varscan2
- CUL9 | c.4498C>T p.R1500C | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764576161, COSV52732560, COSV99335516; called by muse, mutect2, varscan2
- CUZD1 | c.104G>A p.S35N | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.129); catalogued as COSV59027582; called by muse, mutect2
- CXorf66 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.496); catalogued as rs200754289, COSV65169523, COSV65169966; called by muse, mutect2, varscan2
- CXorf66 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.202); catalogued as rs1448732250, COSV65169604; called by muse, mutect2, varscan2
- CYB5R2 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.478); catalogued as COSV55086689; called by muse, mutect2, varscan2
- CYFIP2 | c.2978C>T p.S993F (on ENST00000616178 / NM_001291722.2; = p.S968F on NM_014376.4) | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV59046976; called by muse, varscan2
- CYLC1 | c.1850C>T p.P617L | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.78); catalogued as COSV61414552; called by muse, mutect2, varscan2
- CYP21A2 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 130/393 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as CM031956, COSV64485580; called by muse, mutect2, varscan2
- CYP2C18 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 11/63 reads (17%) | catalogued as COSV53670957, COSV53674193; called by muse, mutect2, varscan2
- CYP2C19 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.203); catalogued as COSV64908837; called by muse, varscan2
- CYP2C19 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.336); catalogued as COSV64908392; called by muse, mutect2, varscan2
- CYP2F1 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs765123717, COSV58528490; called by mutect2, varscan2
- CYP2S1 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59507753; called by muse, mutect2, varscan2
- CYP3A43 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1241084624, COSV55937380; called by muse, mutect2, varscan2
- CYP3A7 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60481634; called by muse, mutect2, varscan2
- CYP4A22 | c.1172G>A p.R391K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV53741746; called by muse, mutect2, varscan2
- CYP4B1 | c.608G>A p.G203D | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.222); catalogued as COSV54725236; called by muse, mutect2, varscan2
- CYP4F11 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56127043; called by muse, mutect2, varscan2
- CYP4F22 | c.613C>T p.L205F | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54110633; called by muse, mutect2, varscan2
- CYP4F22 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as COSV54110642; called by muse, mutect2, varscan2
- CYP4F3 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV55412397; called by muse, mutect2, varscan2
- CYP4F3 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as rs1216034192, COSV55412420; called by muse, mutect2, varscan2
- CYP4X1 | c.673C>T p.H225Y | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64151440; called by muse, mutect2, varscan2
- CYP7A1 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV56964851; called by muse, mutect2
- CYP7B1 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1394828774, COSV59582859; called by muse, varscan2
- CYRIA | c.438G>A p.M146I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV62866389; called by muse, mutect2, varscan2
- DAB2 | c.451A>T p.T151S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs762896206, COSV57917474; called by muse, mutect2, varscan2
- DAB2IP | c.2254C>T p.Q752* (on ENST00000408936; = p.Q724* on NM_032552.3) | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV52265204; called by muse, mutect2
- DACH1 | c.1816C>T p.P606S (on ENST00000619232 / NM_001366712.1; = p.P352S on NM_004392.6) | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.325); catalogued as COSV57492586; called by muse, mutect2, varscan2
- DACH2 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1269727854, COSV64180185; called by muse, mutect2, varscan2
- DAOA | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.977); catalogued as COSV61603259; called by muse, mutect2, varscan2
- DAW1 | c.698G>A p.R233K | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.062); catalogued as COSV59364545, COSV59367791; called by muse, mutect2, varscan2
- DCAF4L2 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs1279696544, COSV60476552; called by muse, mutect2, varscan2
- DCAF8L1 | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV71595446; called by muse, mutect2, varscan2
- DCAF8L1 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.606); catalogued as COSV71595196, COSV71595447; called by muse, mutect2
- DCC | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV59092842; called by muse, varscan2
- DCC | c.4207C>T p.P1403S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV71438374; called by muse, mutect2, varscan2
- DCDC1 | c.792G>A p.M264I | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV60853334; called by muse, mutect2, varscan2
- DCLK1 | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as rs769128085, COSV55169876; called by mutect2, varscan2
- DCLK3 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs764405438, COSV69364239; called by muse, mutect2, varscan2
- DCTN1 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.992); catalogued as rs1471513420, COSV62621153; called by muse, mutect2, varscan2
- DCTN3 | c.142T>G p.S48A | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52408457; called by muse, mutect2, varscan2
- DCUN1D3 | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs1168345295; called by muse, mutect2, varscan2
- DDAH1 | c.315G>A p.M105I | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.043); catalogued as COSV52306387; called by muse, mutect2, varscan2
- DDX10 | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59438239; called by muse, mutect2, varscan2
- DDX58 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV65884295; called by muse, mutect2, varscan2
- DDX60 | c.5062G>A p.E1688K | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV67098383; called by muse, mutect2, varscan2
- DDX60 | c.4090C>T p.L1364F | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as rs774054777, COSV67096167; called by muse, mutect2, varscan2
- DEF6 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.048); catalogued as rs1288931168, COSV57354950; called by muse, mutect2, varscan2
- DEF6 | c.426G>A p.V142= | Splice Region (SNP) | VAF 14/42 reads (33%) | catalogued as COSV57354958; called by muse, mutect2, varscan2
- DEFB115 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.224); catalogued as COSV68723319; called by muse, mutect2, varscan2
- DEFB131A | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.044); catalogued as rs1334210583, COSV58416594; called by muse, mutect2, varscan2
- DEGS2 | c.752G>A p.W251* | Nonsense Mutation (SNP) | VAF 19/128 reads (15%) | catalogued as COSV59785160; called by muse, mutect2, varscan2
- DENND1A | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs767572605, COSV65347728; called by muse, mutect2, varscan2
- DENND2A | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.298); catalogued as rs913049832, COSV52052565; called by muse, mutect2, varscan2
- DENND3 | c.2398G>A p.E800K | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52805227; called by muse, mutect2, varscan2
- DENND4A | c.4273G>A p.E1425K | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.321); catalogued as COSV71266735; called by muse, mutect2, varscan2
- DENND4A | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1467015475, COSV71265893; called by muse, mutect2, varscan2
- DEPDC5 | c.1819C>T p.P607S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.484); catalogued as COSV56705940; called by muse, varscan2
- DGKB | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs377479103; called by muse, mutect2, varscan2
- DGKK | c.3368A>G p.Q1123R | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV65708933; called by muse, mutect2, varscan2
- DHRS1 | c.306C>A p.N102K | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV55385328; called by muse, mutect2, varscan2
- DHX16 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV64565093; called by muse, mutect2, varscan2
- DHX29 | c.1810C>T p.Q604* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as COSV52420698; called by muse, mutect2, varscan2
- DHX57 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54889337; called by muse, mutect2, varscan2
- DIDO1 | c.5339C>T p.P1780L | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.459); catalogued as rs763324231, COSV56618884, COSV56635861; called by muse, mutect2, varscan2
- DIDO1 | c.3779C>T p.S1260L | Missense Mutation (SNP) | VAF 53/194 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV56630834; called by muse, mutect2, varscan2
- DIRAS1 | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV60216401; called by muse, mutect2, varscan2
- DIRAS3 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.115); catalogued as COSV63971076; called by muse, mutect2, varscan2
- DKKL1 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV55563155; called by muse, mutect2, varscan2
- DLG2 | c.2602G>A p.E868K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1406918822, COSV54648141; called by muse, mutect2
- DLG2 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as COSV54672680; called by muse, mutect2, varscan2
- DLGAP2 | c.947A>G p.N316S | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.83); PolyPhen benign (0.006); catalogued as rs751225110, COSV70099462, COSV70102345; called by muse, mutect2, varscan2
- DLGAP4 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV59421634; called by muse, varscan2
- DLGAP4 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.994); catalogued as COSV59421643; called by muse, varscan2
- DLGAP5 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751930287, COSV55964718; called by muse, mutect2, varscan2
- DMRT3 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.468); catalogued as COSV51907131; called by muse, mutect2, varscan2
- DMXL1 | c.3509G>A p.G1170D | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV60718523; called by muse, mutect2, varscan2
- DNAAF1 | c.1285G>A p.V429I | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as rs1267192221, COSV57578409; called by muse, mutect2, varscan2
- DNAH1 | c.2387C>T p.S796L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs369350834; called by muse, mutect2, varscan2
- DNAH1 | c.5428C>T p.P1810S | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776970930, COSV70227861; called by muse, mutect2, varscan2
- DNAH10 | c.4628G>A p.R1543K (on ENST00000409039; = p.R1482K on NM_207437.3) | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); catalogued as COSV68992899, COSV68998847; called by muse, mutect2, varscan2
- DNAH10 | c.9604G>A p.E3202K (on ENST00000409039; = p.E3141K on NM_207437.3) | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as rs762842800, COSV68998858; called by muse, varscan2
- DNAH11 | c.8893G>A p.E2965K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1236937721; called by muse, mutect2, varscan2
- DNAH17 | c.3325G>A p.G1109S | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.05); PolyPhen benign (0.146); catalogued as COSV101102128; called by muse, mutect2, varscan2
- DNAH3 | c.3673A>T p.K1225* | Nonsense Mutation (SNP) | VAF 25/81 reads (31%) | catalogued as COSV54540958; called by muse, mutect2, varscan2
- DNAH5 | c.13843C>T p.R4615C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771613197, COSV54239919; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.12121C>T p.P4041S | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as rs1169918695, COSV54239713; called by muse, mutect2, varscan2
- DNAH5 | c.11888C>T p.S3963L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs191057833, COSV54214570, COSV99445303; called by muse, mutect2, varscan2
- DNAH5 | c.4324A>T p.I1442F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV54243411; called by muse, mutect2, varscan2
- DNAH5 | c.3253G>A p.E1085K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV54243418; called by muse, mutect2, varscan2
- DNAH5 | c.2065C>T p.H689Y | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV54229374; called by mutect2, varscan2
- DNAH7 | c.10778G>A p.R3593Q | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749019068, COSV56767773; called by muse, mutect2, varscan2
- DNAH7 | c.5657G>A p.R1886Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs13034775; called by muse, mutect2, varscan2
- DNAH7 | c.1754G>A p.R585K | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1449586344, COSV56778369; called by muse, mutect2, varscan2
- DNAH8 | c.1639G>A p.G547S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.557); catalogued as rs199536824; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH8 | c.8717G>A p.R2906Q | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs146541069, COSV59437890; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH8 | c.10133T>A p.I3378N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV59470037; called by muse, mutect2, varscan2
- DNAH9 | c.2530G>A p.D844N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV52352887, COSV52376688; called by muse, varscan2
- DNAH9 | c.2581C>T p.H861Y | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as COSV52367250; called by muse, varscan2
- DNAH9 | c.6289C>T p.L2097F | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771595078, COSV52367303; called by muse, mutect2, varscan2
- DNAH9 | c.11678C>T p.S3893L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); catalogued as rs761550523, COSV52367321; called by muse, mutect2, varscan2
- DNAI4 | c.1982C>T p.A661V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); catalogued as COSV100925259, COSV64023092; called by muse, mutect2, varscan2
- DNAJA2 | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 23/103 reads (22%) | catalogued as COSV57695273; called by muse, mutect2, varscan2
- DNASE2B | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV65737176, COSV65738007; called by mutect2, varscan2
- DOCK2 | c.4061C>T p.S1354F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as COSV56978075; called by muse, mutect2, varscan2
- DOCK3 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as rs368554363; called by mutect2, varscan2
- DOCK3 | c.1205G>A p.G402E | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV56540253; called by muse, mutect2, varscan2
- DOCK3 | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56529199; called by muse, mutect2, varscan2
- DOCK4 | c.5198C>T p.P1733L | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs777190065, COSV70241413; called by muse, mutect2, varscan2
- DOP1A | c.6803C>T p.S2268L | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV52711138, COSV52715198; called by muse, mutect2, varscan2
- DPF2 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV52888034; called by muse, mutect2, varscan2
- DPP3 | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.58); catalogued as COSV100855830, COSV64757572; called by muse, mutect2, varscan2
- DPY19L1 | c.1342C>T p.H448Y | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.492); catalogued as rs1159232365, COSV60583555; called by muse, mutect2, varscan2
- DPYS | c.1271A>T p.N424I | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV60911949; called by muse, mutect2, varscan2
- DRC1 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs769270156, COSV55496136; called by muse, mutect2, varscan2
- DSC1 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.04); catalogued as COSV57145208, COSV57149539; called by muse, mutect2, varscan2
- DSC3 | c.969G>A p.M323I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs777231339, COSV64574531; called by muse, mutect2, varscan2
- DSCAM | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV68032832; called by muse, mutect2, varscan2
- DSG1 | c.2563G>A p.D855N | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs561112685, COSV57133677; called by muse, mutect2, varscan2
- DSG3 | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV57128416; called by muse, varscan2
- DSG3 | c.2021C>T p.A674V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57128431; called by muse, mutect2
- DSG3 | c.2255C>T p.A752V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.079); catalogued as COSV57127780; called by muse, mutect2, varscan2
- DSG4 | c.1871C>T p.S624L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as COSV57395362; called by muse, mutect2, varscan2
- DSG4 | c.2123G>A p.R708Q | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.347); catalogued as rs774129203; called by muse, mutect2, varscan2
- DSG4 | c.2291G>A p.G764E | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1373560556, COSV57395381; called by muse, mutect2, varscan2
- DSG4 | c.2704C>T p.H902Y | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100356515, COSV57394105; called by muse, mutect2, varscan2
- DUSP13 | c.179G>A p.W60* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as COSV57815773; called by muse, mutect2, varscan2
- DYDC2 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV55473022; called by muse, mutect2, varscan2
- DYNC2I1 | c.2315C>T p.S772L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV68104165; called by muse, mutect2, varscan2
- DYSF | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV50386101, COSV50531125; called by muse, mutect2, varscan2
- DYTN | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV71751604; called by muse, mutect2
- E2F8 | c.2554C>G p.L852V | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.036); catalogued as COSV51465338; called by muse, mutect2, varscan2
- EBF1 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.838); catalogued as COSV58189475, COSV58194578; called by muse, mutect2, varscan2
- ECT2L | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV62886295; called by muse, mutect2, varscan2
- ECT2L | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV62886300; called by muse, mutect2, varscan2
- EDDM3A | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58795431; called by muse, mutect2, varscan2
- EDN1 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65081172; called by muse, mutect2, varscan2
- EED | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54557571; called by muse, mutect2, varscan2
- EFCAB13 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 78/134 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.448); catalogued as COSV58951254; called by muse, varscan2
- EFCAB13 | c.1869G>A p.W623* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as COSV58951266; called by muse, mutect2, varscan2
- EFCAB6 | c.3934C>T p.P1312S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV53069146; called by muse, varscan2
- EFCAB6 | c.2696G>A p.G899E | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV53069158, COSV53073789; called by muse, mutect2, varscan2
- EFEMP1 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); catalogued as COSV62617330; called by muse, mutect2, varscan2
- EFEMP1 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.778); catalogued as COSV62617337; called by muse, mutect2, varscan2
- EGFLAM | c.810G>T p.L270F | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as COSV59310531, COSV59312371; called by muse, varscan2
- EGFLAM | c.2999C>T p.S1000F (on ENST00000354891 / NM_001205301.2; = p.S992F on NM_152403.4) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.534); catalogued as COSV59312411; called by muse, mutect2, varscan2
- EGFR | c.139C>T p.H47Y | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV51779748; called by muse, mutect2, varscan2
- EGFR | c.2764G>A p.E922K | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.701); catalogued as rs961150162, COSV51830943; called by muse, mutect2, varscan2
- EIF2B4 | c.295G>A p.E99K (on ENST00000347454 / NM_001034116.2; = p.E98K on NM_015636.3) | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs758233858, COSV52009509; called by muse, mutect2, varscan2
- EIF4G1 | c.3123C>T p.S1041= (on ENST00000346169 / NM_198241.3; = p.S846= on NM_004953.5) | Splice Region (SNP) | VAF 43/197 reads (22%) | catalogued as rs775684766, COSV59992828; called by muse, varscan2
- ELAPOR1 | c.2854G>A p.D952N | Missense Mutation (SNP) | VAF 176/542 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs866285242; called by muse, mutect2, varscan2
- ELAPOR2 | c.2640G>C p.E880D (on ENST00000450689 / NM_001142749.3; = p.E713D on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as COSV51890141; called by muse, mutect2, varscan2
- ELOA2 | c.1892G>A p.G631E | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV55295242, COSV55302096; called by muse, mutect2, varscan2
- ELOA2 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.901); catalogued as rs955368469, COSV55305056; called by muse, mutect2, varscan2
- EMB | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57483692; called by muse, mutect2, varscan2
3,907 further variants in this file (2,204 protein-altering or splice-affecting, 1,608 silent, 95 other) are not listed here.
